Somatic mutation profile of tumor specimen TCGA-WB-A81J-01A (aliquot TCGA-WB-A81J-01A-11D-A35I-08) from TCGA case TCGA-WB-A81J, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Pheochromocytoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 40.2 years (14,665 days).
Specimen TCGA-WB-A81J-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 64ccc202-deb9-4535-b551-fe1e3f449dac.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-WB-A81J-10A (Blood Derived Normal), aliquot TCGA-WB-A81J-10A-01D-A35G-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9fe6f21d-7be5-4279-ad29-c19053aadcf6

The open-access MAF lists 9 somatic variants for this specimen: 9 protein-altering or splice-affecting.
By variant classification: Missense Mutation 8, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP10D | c.2854-2A>G p.X952_splice | Splice Site (SNP) | VAF 25/28 reads (89%) | catalogued as rs1224793126; called by muse, mutect2, varscan2
- DIDO1 | c.4750C>A p.R1584S | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as rs767587220; called by muse, mutect2, varscan2
- ABCA13 | c.11830G>A p.A3944T | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.566); called by muse, mutect2, varscan2
- C2orf16 | c.4036C>A p.Q1346K | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.031); called by muse, mutect2
- CBLN2 | c.661G>T p.V221L | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT tolerated (0.52); PolyPhen benign (0.17); called by muse, mutect2, varscan2
- CRYBB1 | c.505G>C p.D169H | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- SERTM1 | c.261C>G p.F87L | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- VWA3B | c.3680C>T p.S1227F | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.466); called by muse, varscan2
- XRN1 | c.3892A>G p.K1298E | Missense Mutation (SNP) | VAF 41/76 reads (54%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.013); called by muse, mutect2, varscan2
